CTSP case CTSP-ACYM — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59a39f8f-6a36-4d83-9f6d-a7460ceb8e1f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 56.2 years (20,535 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage II; Days to last follow up: 1,946 days (5.3 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: No; Double hit lymphoma: No; International Prognostic Index (IPI): Low Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 134 kg; Height: 185 cm; BMI: 39.2.

Biospecimens (1 sample)
- Sample DLBCL11290-sample: Sample type: Tumor; Tissue type: Tumor.
